MMRF case MMRF_1951 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c8e4e627-08ef-450b-938e-790c072b7803

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 77 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.8 years (28,406 days); ISS stage: III; Days to last known disease status: 1,069 days (2.9 years); Days to last follow up: 1,069 days (2.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 607 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 614 days (1.7 years); Days to treatment end: 617 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 656 days (1.8 years); Days to treatment end: 918 days (2.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 899 days (2.5 years); Days to treatment end: 972 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Lenalidomide; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 930 days (2.5 years); Days to treatment end: 972 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 986 days (2.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 2.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 112 mg/dL; Immunoglobulin G 40.6 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 6.94 µg/mL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 8.9 g/dL; Glucose 4.84 mmol/L.
- Day 102 (ECOG 0): M Protein 0.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.9 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 300 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.05 mmol/L; Albumin 32 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 172 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.49 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 6.82 mmol/L.
- Day 273 (ECOG 1): M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.51 mg/dL; Immunoglobulin G 9.61 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 2.67 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 78 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 4.46 mmol/L.
- Day 369 (ECOG 1): M Protein 0.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.832 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.33 mg/dL; Immunoglobulin G 9.21 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 6.33 mmol/L.
- Day 452 (ECOG 1): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.5 mg/dL; Immunoglobulin G 7.9 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 10.8 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 6.2 g/dL; Glucose 5.01 mmol/L.
- Day 523 (ECOG 1): M Protein 0.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.27 mg/dL; Immunoglobulin G 9.58 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 83 ×10⁹/L; Creatinine 152 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 7.32 mmol/L.
- Day 614 (ECOG 1): M Protein 0.78 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.2 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 5.23 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 90 ×10⁹/L; Creatinine 145 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.1 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 4.79 mmol/L.
- Day 712 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 4.78 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 4.24 mmol/L.
- Day 810 (ECOG 1): M Protein 0 g/dL; Hemoglobin 5.95 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.08 mmol/L; Albumin 26 g/L; Total Protein 4.8 g/dL; Glucose 4.46 mmol/L.
- Day 883 (ECOG 1): M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.32 mg/dL; Immunoglobulin G 7.63 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 4.37 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 7.21 mmol/L.
- Day 986 (ECOG 1): M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.9 mg/dL; Immunoglobulin G 8.04 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 4.76 µg/mL; Lactate Dehydrogenase 11.9 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 5.67 mmol/L.
- Day 1,069 (ECOG 1): M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.7 mg/dL; Immunoglobulin G 9.33 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 1.95 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -3: Weight: 72 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_1951_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1951_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
